Surgical pathology report (de-identified scan), TCGA case TCGA-5U-AB0F, project TCGA-THYM (Thymoma), tissue source site Regina Elena National Cancer Institute, specimen TCGA-5U-AB0F-01A (Primary Tumor).

ICD-O-3
Thymoma, type AB malignant 8582/3
Site: Anterior mediastinum C38.1
JW 5/21/14

SURNAME and NAME :

Sex: F

BIRTH DATE:

Hospital:

Department: Thoracic Surgery

Clinical informations: Anterior mediastinal mass 8.2x7.5x5.5 ; hepatic cirrosis HBV-related

Type of specimen: radical Thymectomy according to + pericardium island + atypical lung resection superior right lobe

Material sent: A) cardio-phrenic right adipous tissue; B) aorto-pulmonary window lymph nodes; C) pericardium-thymoma-thymus-atypical lung resection; D) precaval lymph nodes.

Macroscopical description: A) cardio-phrenic right adipous tissue: adipous tissue cm 3.5x3.5x1, block no. 1; B) aorto-pulmonary window lymph nodes: block no.2, all the material embedded; C) pericardium-thymoma-thymus-atypical lung resection: (oriented specimen): 8x6.5x4.5 mass, laterally adherent to atypical lung resection measuring cm 10x2.5x1.2 and posteriorly adhering to a pericardial plaque of 7x4.5 cm. The mass is encapsulated, although on the right the capsule is very thin (ink-marked margins). Sampling: 3-7 anterior part of the neoplasia, 8-11 posterior part of the neoplasia; 12-14 sampling of adipous tissue ; 15 nodule in the posterior adipous tissue; D) precaval lymph nodes: adipous tissue ,all the material embedded on block no. 16.

Diagnosis: A) cardio-phrenic right adipous tissue: adipous and fibrous tissues without alterations; B) aorto-pulmonary window lymph nodes: 3 reactive lymph nodes; C) pericardium-thymoma-thymus- atypical lung resection: AB thymoma according to the 2004 WHO classification, partially encapsulated, focally infiltrating the lung atypical resection; the pericardium is free from neoplastic infiltration. Adjacent to the neoplasia scant thymic remnants were found. Immunohistochemical staining showed that the lymphocytes are mostly cortical T-lymphocytes; epithelial cells tested do not express aberrantly CD20 or CD5. In the tumor and in the thymic remnants rare B lymphocytes CD20+ were found ; D) precaval lymph nodes: 4 reactive lymph nodes.

Staging according to Masaoka: St III, pN0.

Acceptance date:

Reporting date:

Pathologist

Source: NCI Genomic Data Commons file 9f8d9fcc-cef4-4565-a0e3-b94dbf456f8c (TCGA-5U-AB0F.FA2A1A2E-8B57-4676-B1B2-814CC89B0A77.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).